Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3SE, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3SE-01A (Primary Tumor).

- LAB RESULTS

		W 3/20/12

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

- 1) NECK (EXCISION): FIBROADIPOSE TISSUE WITH ACUTE INFLAMMATION.
- 2) NECK (EXCISION): FIBROADIPOSE TISSUE.
- 3) NECK (EXCISION): PARATHYROID TISSUE.
- 4) THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:
Total thyroidectomy.

TUMOR SITE:
Right lobe
Isthmus
Left lobe

HISTOLOGIC TYPE:
Papillary carcinoma.

TUMOR SIZE:
Greatest dimension: 3.5 cm.

FOCALITY:
Multifocal

LYMPH NODES:
Metastatic carcinoma in 2 of 8 lymph nodes.

EXTENT OF INVASION
PRIMARY TUMOR:
pT2: Tumor >2 cm but <4 cm, limited to thyroid.

REGIONAL LYMPH NODES:
pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes.

DISTANT METASTASIS:
pMx: Cannot be assessed

MARGINS:
Margins are uninvolved.

VENOUS/LYMPHATIC INVASION:
Absent.

5) NECK (LEFT CENTRAL NECK DISSECTION): METASTATIC PAPILLARY CARCINOMA IN TWO (2) OF SEVEN (7) LYMPH NODES. HISTOLOGICALLY UNREMARKABLE THYMUS.

Reported by:

Final Report Signed on

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

S112
R0

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 4f1fa593-2702-4753-9058-0674242c80d7 (TCGA-FK-A3SE.3489196F-F9FD-4797-B4F2-0D66D420102A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).